Somatic mutation profile of tumor specimen TCGA-CV-6948-01A (aliquot TCGA-CV-6948-01A-11D-1912-08) from TCGA case TCGA-CV-6948, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G2; Age at diagnosis: 79.8 years (29,153 days).
Specimen TCGA-CV-6948-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cfdf9e2a-ebab-4afd-9a58-30e80cb7650b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-6948-10A (Blood Derived Normal), aliquot TCGA-CV-6948-10A-01D-1912-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dae41dbd-c314-407c-8b28-d75f2e17717b

The open-access MAF lists 205 somatic variants for this specimen: 151 protein-altering or splice-affecting, 51 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 117, Silent 51, Nonsense Mutation 13, Splice Site 7, Frame Shift Ins 5, Frame Shift Del 5, Intron 2, Splice Region 2, 3'UTR 1, In Frame Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>G p.R505G (on ENST00000281708 / NM_001349798.2; = p.R425G on NM_018315.5) | Missense Mutation (SNP) | VAF 55/72 reads (76%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- LRPPRC | c.2505-1G>T p.X835_splice | Splice Site (SNP) | VAF 24/66 reads (36%) | catalogued as rs1553400727, COSV99580212; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 16/107 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.920-2A>G p.X307_splice | Splice Site (SNP) | VAF 46/93 reads (49%) | hotspot (GDC flag); catalogued as rs397516439, COSV52693974, COSV52706655, COSV52945558, COSV53066011; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- AC100868.1 | c.1882C>T p.L628F | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.615); catalogued as COSV99225562; called by muse, mutect2, varscan2
- ACSL5 | c.182A>G p.Q61R (on ENST00000354273; = p.Q117R on NM_016234.3) | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0.045); catalogued as COSV100634528; called by muse, mutect2, varscan2
- ACSS2 | c.806del p.P269Qfs*69 | Frame Shift Del (DEL) | VAF 18/74 reads (24%) | catalogued as rs745681981, COSV53623223; called by mutect2, pindel, varscan2
- AHNAK2 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.13); catalogued as COSV100316469; called by muse, mutect2, varscan2
- AKAP8L | c.303G>A p.M101I | Missense Mutation (SNP) | VAF 72/187 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV101275755; called by muse, mutect2, varscan2
- AOAH | c.889G>C p.D297H | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV51750814, COSV99332398; called by muse, mutect2, varscan2
- AP1G2 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as rs757149895, COSV100436619; called by muse, mutect2, varscan2
- APC | c.4700C>G p.S1567* | Nonsense Mutation (SNP) | VAF 34/51 reads (67%) | catalogued as CM920055, COSV57331707, COSV57333355, COSV57395886; called by muse, mutect2, varscan2
- ARHGEF35 | c.121C>G p.Q41E | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV100967687; called by mutect2, varscan2
- ATP8A1 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as rs373363487; called by muse, mutect2, varscan2
- B3GAT3 | c.460C>T p.H154Y | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV53881216; called by muse, mutect2, varscan2
- BAG4 | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.642); catalogued as rs1020991875, COSV99781765; called by muse, mutect2, varscan2
- BRINP1 | c.1828A>C p.T610P | Missense Mutation (SNP) | VAF 122/153 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99774875; called by muse, mutect2, varscan2
- BSX | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755017837, COSV58006536; called by muse, mutect2, varscan2
- BTN3A3 | c.1506G>T p.L502F | Missense Mutation (SNP) | VAF 44/180 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.593); catalogued as COSV99764810; called by muse, mutect2, varscan2
- CACNA1H | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1005279922, COSV100671400; called by muse, mutect2, varscan2
- CAMTA1 | c.3853G>A p.E1285K | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.427); catalogued as rs375995525, COSV57894174; called by muse, mutect2, varscan2
- CARD11 | c.2189C>T p.T730I | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as COSV100829107; called by muse, mutect2, varscan2
- CC2D1B | c.1507G>C p.A503P | Missense Mutation (SNP) | VAF 34/47 reads (72%) | SIFT tolerated (0.2); PolyPhen benign (0.33); catalogued as COSV99429786; called by muse, mutect2, varscan2
- CCDC151 | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV100710474, COSV62697338; called by muse, mutect2, varscan2
- CCDC88C | c.1426C>T p.Q476* | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as COSV101105358; called by muse, mutect2, varscan2
- CERT1 | c.487A>G p.N163D (on ENST00000405807 / NM_001130105.1; = p.N35D on NM_005713.3) | Missense Mutation (SNP) | VAF 27/32 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99783032; called by muse, mutect2, varscan2
- CIBAR1 | c.58G>T p.V20F | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100844643; called by muse, mutect2, varscan2
- CIITA | c.2848G>T p.E950* | Nonsense Mutation (SNP) | VAF 12/38 reads (32%) | catalogued as COSV100161589, COSV60859669; called by muse, mutect2, varscan2
- CKM | c.1019A>G p.D340G | Missense Mutation (SNP) | VAF 60/187 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99487975; called by muse, mutect2, varscan2
- CLCA1 | c.2071C>T p.Q691* | Nonsense Mutation (SNP) | VAF 22/30 reads (73%) | catalogued as COSV99322066; called by muse, mutect2, varscan2
- CLPTM1 | c.1975C>T p.P659S | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV61610879; called by muse, mutect2, varscan2
- CLVS1 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.729); catalogued as COSV100369477, COSV100369644; called by muse, mutect2, varscan2
- CSPG4 | c.955C>T p.R319W | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); catalogued as rs777887485, COSV57892138; called by muse, mutect2, varscan2
- CYLC2 | c.395C>G p.S132* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100872396; called by muse, mutect2
- DALRD3 | c.1106C>T p.T369I (on ENST00000341949 / NM_001009996.3; = p.T202I on NM_018114.5) | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV100482772; called by muse, mutect2, varscan2
- DCAF16 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 68/127 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs952623487, COSV101200405; called by muse, mutect2, varscan2
- DEFB116 | c.281C>A p.T94K | Missense Mutation (SNP) | VAF 84/276 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1475529383, COSV101269216; called by muse, mutect2, varscan2
- DHX16 | c.2368C>A p.L790M | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV99527805; called by muse, mutect2, varscan2
- DVL3 | c.1393C>T p.R465C | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1463261176, COSV100493500; called by muse, mutect2, varscan2
- DYNC2H1 | c.1498A>C p.I500L | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV100517984; called by muse, mutect2, varscan2
- E2F5 | c.775C>G p.P259A | Missense Mutation (SNP) | VAF 6/119 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.08); catalogued as COSV99809375; called by muse, mutect2
- EIF3E | c.210G>C p.L70F | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.316); catalogued as COSV99622936; called by muse, mutect2, varscan2
- ENTPD6 | c.711C>A p.G237= | Splice Region (SNP) | VAF 10/29 reads (34%) | catalogued as COSV100737016; called by muse, mutect2, varscan2
- FAM8A1 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as rs1366000323, COSV52580283, COSV52580559; called by muse, mutect2, varscan2
- FBXO30 | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99395073; called by muse, mutect2, varscan2
- FGF23 | c.428G>C p.R143T | Missense Mutation (SNP) | VAF 76/194 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as COSV99426320; called by muse, mutect2, varscan2
- FSCN1 | c.209T>A p.L70Q | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100435096; called by muse, mutect2, varscan2
- GAN | c.1466C>T p.T489I | Missense Mutation (SNP) | VAF 98/198 reads (49%) | SIFT tolerated (0.44); PolyPhen benign (0.351); catalogued as COSV101633947; called by muse, mutect2, varscan2
- GDF3 | c.1013C>T p.S338F | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs968641196, COSV61713479; called by muse, mutect2, varscan2
- GRIP2 | c.736G>A p.V246I (on ENST00000619221; = p.V149I on NM_001080423.4) | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as rs1225980454, COSV56122570; called by muse, mutect2, varscan2
- GRSF1 | c.360G>A p.E120= | Splice Region (SNP) | VAF 36/96 reads (38%) | catalogued as COSV99635581; called by muse, mutect2, varscan2
- HNRNPL | c.521C>G p.S174C | Missense Mutation (SNP) | VAF 53/159 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV99670135, COSV99670600; called by muse, mutect2, varscan2
- HTR1B | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 83/218 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.129); catalogued as COSV100885362; called by muse, mutect2, varscan2
- IHO1 | c.395+1G>T p.X132_splice | Splice Site (SNP) | VAF 14/20 reads (70%) | catalogued as COSV99605946; called by muse, mutect2, varscan2
- IL22 | c.436C>A p.Q146K | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV100048792; called by muse, mutect2, varscan2
- IL2RA | c.613G>A p.G205S | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs772770506, COSV99906587; called by muse, mutect2, varscan2
- IQCN | c.3088G>A p.D1030N | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.681); catalogued as COSV100828210; called by muse, mutect2, varscan2
- ITGAD | c.1267G>T p.A423S | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV101210393, COSV66760734; called by muse, mutect2, varscan2
- ITGAE | c.2999G>A p.G1000E | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as COSV99560629; called by muse, mutect2, varscan2
- KDM4C | c.158A>T p.K53M | Missense Mutation (SNP) | VAF 20/24 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as COSV101184715; called by muse, mutect2, varscan2
- KIAA1614 | c.2980A>G p.K994E | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV100799749; called by muse, mutect2
- KLHL23 | c.77T>C p.F26S | Missense Mutation (SNP) | VAF 5/130 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV99775634; called by muse, mutect2
- KLHL28 | c.825G>A p.M275I | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100753029; called by muse, mutect2, varscan2
- KMT2B | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.052); catalogued as COSV99385920; called by muse, mutect2, varscan2
- KRT76 | c.1424A>C p.K475T | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100195919; called by muse, mutect2
- LAMB3 | c.2462T>G p.V821G | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100620181; called by muse, mutect2, varscan2
- LARP4B | c.1543C>T p.Q515* | Nonsense Mutation (SNP) | VAF 24/75 reads (32%) | catalogued as COSV100295177; called by muse, mutect2, varscan2
- LIN9 | c.1045G>A p.E349K (on ENST00000366808 / NM_001270410.2; = p.E294K on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100067211; called by muse, mutect2, varscan2
- LRP1 | c.10345+2T>C p.X3449_splice | Splice Site (SNP) | VAF 51/143 reads (36%) | catalogued as rs111522273, COSV99675078; called by muse, mutect2, varscan2
- MACF1 | c.22075G>A p.G7359R (on ENST00000372915; = p.G5404R on NM_012090.5) | Missense Mutation (SNP) | VAF 7/150 reads (5%) | catalogued as COSV99242591; called by muse, mutect2
- MAGED1 | c.979C>T p.Q327* | Nonsense Mutation (SNP) | VAF 32/42 reads (76%) | catalogued as COSV100431453; called by muse, mutect2, varscan2
- MARK4 | c.106del p.R36Afs*27 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | catalogued as COSV99488120; called by mutect2, pindel, varscan2
- MCM10 | c.2131G>T p.E711* (on ENST00000484800 / NM_182751.3; = p.E710* on NM_018518.5) | Nonsense Mutation (SNP) | VAF 50/118 reads (42%) | catalogued as rs754834955, COSV101098013; called by muse, mutect2, varscan2
- MDM1 | c.610G>T p.A204S | Missense Mutation (SNP) | VAF 110/511 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV100291717; called by muse, mutect2, varscan2
- MORC3 | c.1871C>G p.S624* | Nonsense Mutation (SNP) | VAF 36/124 reads (29%) | catalogued as COSV101264883; called by muse, mutect2, varscan2
- MRPS22 | c.649A>G p.M217V (on ENST00000310776 / NM_001363893.1; = p.M218V on NM_020191.4) | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201627731, COSV100169000; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTHFD1 | c.757G>T p.V253L | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as COSV99386691; called by muse, mutect2
- MYC | c.1167G>C p.K389N (on ENST00000377970; = p.K404N on NM_002467.6) | Missense Mutation (SNP) | VAF 67/395 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52380993, COSV99419762, COSV99422120; called by muse, mutect2, varscan2
- MYCBP2 | c.9619G>C p.G3207R (on ENST00000357337; = p.G3245R on NM_015057.5) | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100629610; called by muse, mutect2, varscan2
- NAALAD2 | c.1281G>C p.E427D | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as COSV100428185; called by muse, mutect2, varscan2
- NAV2 | c.2533G>A p.V845M (on ENST00000396087 / NM_001244963.2; = p.V822M on NM_145117.5) | Missense Mutation (SNP) | VAF 48/64 reads (75%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100585164; called by muse, mutect2, varscan2
- NLRP14 | c.413G>T p.W138L | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100204741; called by muse, mutect2, varscan2
- NOS2 | c.32C>G p.T11S | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0.009); catalogued as COSV100569546; called by muse, mutect2, varscan2
- NOTCH3 | c.4316A>G p.N1439S | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV99656385; called by muse, mutect2, varscan2
- NRK | c.3560T>C p.V1187A | Missense Mutation (SNP) | VAF 66/96 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54599347, COSV99687040; called by muse, mutect2, varscan2
- NYNRIN | c.3179C>T p.A1060V | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV66844962; called by muse, mutect2
- OR10A6 | c.196T>G p.L66V | Missense Mutation (SNP) | VAF 66/97 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59164986; called by muse, mutect2, varscan2
- OR10H5 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs879072736, COSV100454661, COSV104395169; called by muse, mutect2
- OR11L1 | c.179A>T p.Y60F | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.144); catalogued as COSV100869398; called by muse, mutect2, varscan2
- OR1C1 | c.538G>C p.D180H | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101376187, COSV101376201; called by muse, mutect2, varscan2
- OR5H1 | c.236C>A p.P79Q | Missense Mutation (SNP) | VAF 93/350 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100641647, COSV100641757; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.491G>A p.R164Q (on ENST00000259318 / NM_001136562.3; = p.R395Q on NM_007203.5) | Missense Mutation (SNP) | VAF 48/57 reads (84%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as rs376721653; called by muse, mutect2, varscan2
- PANK3 | c.636-2A>C p.X212_splice | Splice Site (SNP) | VAF 45/272 reads (17%) | catalogued as COSV99496246; called by muse, mutect2, varscan2
- PCDHGA7 | c.905C>A p.S302* | Nonsense Mutation (SNP) | VAF 19/56 reads (34%) | catalogued as COSV99533835; called by muse, mutect2, varscan2
- PDLIM5 | c.95G>A p.S32N | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV58749045; called by muse, mutect2, varscan2
- PHF20 | c.1951G>A p.E651K | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs755833178, COSV100179970; called by muse, mutect2, varscan2
- PIK3CB | c.2488G>A p.A830T | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV100005365; called by muse, mutect2, varscan2
- PPEF2 | c.97T>G p.Y33D | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs199757510, COSV99714300; called by muse, mutect2, varscan2
- PPP4R4 | c.1945G>T p.E649* | Nonsense Mutation (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100428415; called by muse, mutect2, varscan2
- PRAG1 | c.1531G>T p.E511* | Nonsense Mutation (SNP) | VAF 14/23 reads (61%) | catalogued as rs760794274, COSV100421997; called by muse, mutect2, varscan2
- PREX2 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.297); catalogued as COSV99905920; called by muse, mutect2, varscan2
- PRKD3 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.15); catalogued as COSV99305892; called by muse, mutect2, varscan2
- PRR3 | c.461-1G>T p.X154_splice | Splice Site (SNP) | VAF 86/306 reads (28%) | catalogued as rs79542230, COSV100925400; called by muse, mutect2, varscan2
- PTPRM | c.2747A>C p.D916A | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as COSV100156034; called by muse, mutect2
- RAB1B | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 85/253 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as COSV100270613, COSV100270620, COSV57584627; called by muse, mutect2, varscan2
- RAB26 | c.349-1G>T p.X117_splice | Splice Site (SNP) | VAF 18/50 reads (36%) | catalogued as COSV99269868; called by muse, mutect2, varscan2
- RAG2 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 41/66 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100270993, COSV100271167; called by muse, mutect2, varscan2
- RFC2 | c.844C>T p.L282F (on ENST00000055077 / NM_181471.3; = p.L248F on NM_002914.4) | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV99277780; called by muse, mutect2, varscan2
- RFWD3 | c.56A>T p.Q19L | Missense Mutation (SNP) | VAF 131/328 reads (40%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV100736195; called by muse, mutect2, varscan2
- RMDN1 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 99/268 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV52207282; called by muse, mutect2, varscan2
- RNFT1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs754999301, COSV99994363; called by muse, varscan2
- RSPH10B | c.2242G>A p.E748K | Missense Mutation (SNP) | VAF 80/283 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.196); catalogued as COSV100382743; called by muse, mutect2, varscan2
- SIGLEC5 | c.542C>T p.T181M | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.39); catalogued as rs776241864, COSV55780704; called by muse, varscan2
- SLC23A1 | c.1655T>C p.I552T | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1318768903, COSV99497192; called by muse, mutect2, varscan2
- SLC35F1 | c.424G>T p.A142S | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as COSV100837678; called by muse, mutect2, varscan2
- SLC37A1 | c.514G>A p.G172S | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771511410, COSV61401439; called by muse, mutect2, varscan2
- SLC5A5 | c.808G>A p.V270M | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as rs368434203; called by muse, mutect2, varscan2
- SLC5A7 | c.1132G>A p.V378I | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT tolerated (0.76); PolyPhen benign (0.005); catalogued as rs763020957, COSV50890306; called by muse, mutect2, varscan2
- SNX27 | c.1030C>T p.Q344* | Nonsense Mutation (SNP) | VAF 30/130 reads (23%) | catalogued as COSV100918994; called by muse, mutect2, varscan2
- SORBS2 | c.1692dup p.A565Rfs*10 | Frame Shift Ins (INS) | VAF 28/46 reads (61%) | catalogued as rs763107670, COSV99510297; called by mutect2, varscan2
- STAB2 | c.4795A>T p.I1599F | Missense Mutation (SNP) | VAF 75/91 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV101185742; called by muse, mutect2, varscan2
- SUN5 | c.322C>G p.L108V | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.1); catalogued as COSV100644797; called by muse, mutect2, varscan2
- SUPT6H | c.1696C>T p.P566S | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100112219; called by muse, mutect2, varscan2
- SYNE2 | c.7913C>G p.T2638S | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV100647125; called by muse, mutect2, varscan2
- TCIRG1 | c.1609A>T p.M537L | Missense Mutation (SNP) | VAF 65/155 reads (42%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as COSV99693219; called by muse, mutect2, varscan2
- TLK2 | c.2137G>C p.E713Q (on ENST00000326270 / NM_001284333.2; = p.E691Q on NM_006852.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100408873, COSV100409701; called by muse, mutect2, varscan2
- TLR1 | c.1545G>T p.K515N | Missense Mutation (SNP) | VAF 128/179 reads (72%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV100458377; called by muse, mutect2, varscan2
- TLX1 | c.113C>G p.S38W | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); catalogued as COSV64622382, COSV64622417; called by muse, mutect2, varscan2
- TMPRSS12 | c.878G>A p.G293D | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101269090; called by muse, mutect2, varscan2
- TPR | c.2407G>C p.E803Q | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100823752; called by muse, mutect2, varscan2
- TRIM27 | c.1459C>G p.L487V | Missense Mutation (SNP) | VAF 58/124 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101019254; called by muse, mutect2, varscan2
- TRIM40 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 64/147 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.494); catalogued as COSV57156364; called by muse, mutect2, varscan2
- UBN2 | c.3305G>C p.S1102T | Missense Mutation (SNP) | VAF 66/136 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.914); catalogued as rs760237214, COSV99943767; called by muse, mutect2, varscan2
- USF3 | c.5347C>T p.P1783S | Missense Mutation (SNP) | VAF 103/375 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.686); catalogued as rs1489766325, COSV100324928; called by muse, mutect2, varscan2
- VASP | c.955A>T p.R319W | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99840882; called by muse, mutect2, varscan2
- VEGFC | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.139); catalogued as rs776421656, COSV99709233; called by muse, mutect2, varscan2
- VPS13B | c.3910G>A p.D1304N | Missense Mutation (SNP) | VAF 101/238 reads (42%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.963); catalogued as COSV100661336; called by muse, mutect2, varscan2
- VPS50 | c.49C>G p.Q17E | Missense Mutation (SNP) | VAF 68/194 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); catalogued as COSV99297905; called by muse, mutect2, varscan2
- ZNF507 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT tolerated (0.71); PolyPhen benign (0.026); catalogued as COSV100321670; called by muse, mutect2, varscan2
- ZNF768 | c.1135G>T p.G379C | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100776122, COSV100776143; called by muse, mutect2, varscan2
- ZNF846 | c.1234C>A p.H412N | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101194279; called by muse, mutect2, varscan2
- ZSWIM8 | c.1779T>A p.S593R | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.095); catalogued as COSV101289848; called by muse, mutect2, varscan2
- AHDC1 | c.2835dup p.K946Qfs*40 | Frame Shift Ins (INS) | VAF 45/84 reads (54%) | called by mutect2, pindel, varscan2
- AKAP1 | c.1887dup p.V630Cfs*77 | Frame Shift Ins (INS) | VAF 67/188 reads (36%) | called by mutect2, pindel, varscan2
- ETV5 | c.535dup p.H179Pfs*31 | Frame Shift Ins (INS) | VAF 44/182 reads (24%) | called by mutect2, pindel, varscan2
- LRRC19 | c.53_55del p.L18del | In Frame Del (DEL) | VAF 14/30 reads (47%) | called by pindel, varscan2
- PRUNE2 | c.8681_8699del p.I2894Sfs*17 | Frame Shift Del (DEL) | VAF 10/71 reads (14%) | called by mutect2, pindel
- RREB1 | c.441_463del p.E148Sfs*11 | Frame Shift Del (DEL) | VAF 23/110 reads (21%) | called by mutect2, pindel, varscan2
- SLITRK5 | c.389dup p.L131Ffs*9 | Frame Shift Ins (INS) | VAF 60/187 reads (32%) | called by pindel, varscan2
- TP53 | c.905_906del p.G302Efs*3 | Frame Shift Del (DEL) | VAF 34/112 reads (30%) | called by pindel, varscan2
- TRAV12-2 | c.154C>A p.Q52K | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- AATF | c.87G>A p.E29= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as rs778372354; called by muse, mutect2
- ABCG8 | c.1048C>T p.L350= | Silent (SNP) | VAF 53/127 reads (42%) | catalogued as COSV99699580; called by muse, mutect2, varscan2
- ASAP1 | c.2718A>G p.T906= | Silent (SNP) | VAF 88/390 reads (23%) | catalogued as COSV100726990; called by muse, mutect2, varscan2
- ATP8B4 | c.1173C>A p.S391= | Silent (SNP) | VAF 25/28 reads (89%) | catalogued as COSV52710285, COSV99464462; called by muse, mutect2, varscan2
- C20orf27 | c.159C>G p.V53= (on ENST00000379772 / NM_001258429.2; = p.V78= on NM_001039140.3) | Silent (SNP) | VAF 7/168 reads (4%) | catalogued as COSV53924668, COSV99422073; called by muse, mutect2
- CCT5 | c.501G>A p.Q167= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as COSV99725180; called by muse, mutect2, varscan2
- CDKN2AIP | c.375G>A p.V125= | Silent (SNP) | VAF 18/29 reads (62%) | catalogued as COSV100187572; called by muse, mutect2, varscan2
- COQ8A | c.1008C>T p.F336= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as rs758871135, COSV100825591; called by muse, mutect2, varscan2
- CR1 | c.3507C>A p.G1169= | Silent (SNP) | VAF 13/208 reads (6%) | called by muse, mutect2
- EDEM1 | c.1107G>A p.L369= | Silent (SNP) | VAF 67/98 reads (68%) | catalogued as rs1331534382, COSV99849090; called by muse, mutect2, varscan2
- EFEMP1 | c.18C>T p.F6= | Silent (SNP) | VAF 73/154 reads (47%) | catalogued as rs182486751; called by muse, mutect2, varscan2
- EXOC4 | c.2406G>T p.V802= | Silent (SNP) | VAF 7/113 reads (6%) | catalogued as COSV99552971; called by muse, mutect2
- F10 | c.30C>T p.L10= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV100660972; called by muse, mutect2, varscan2
- FARP2 | c.1215C>G p.A405= | Silent (SNP) | VAF 30/94 reads (32%) | catalogued as COSV99884221; called by muse, mutect2, varscan2
- HDGFL3 | c.465C>T p.S155= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV100220599; called by muse, mutect2, varscan2
- HECTD4 | c.6798G>A p.G2266= | Silent (SNP) | VAF 45/70 reads (64%) | catalogued as rs1255901854, COSV101106992; called by muse, mutect2, varscan2
- HHIPL1 | c.1236C>T p.R412= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as COSV100415034; called by muse, mutect2, varscan2
- HTR5A | c.294G>A p.L98= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV55286229, COSV99839541; called by muse, mutect2, varscan2
- KIF3C | c.978C>G p.L326= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as COSV99267178; called by muse, mutect2, varscan2
- LEFTY2 | c.1044G>T p.V348= | Silent (SNP) | VAF 35/96 reads (36%) | catalogued as COSV100832551; called by muse, mutect2, varscan2
- LIPN | c.51T>C p.N17= | Silent (SNP) | VAF 45/117 reads (38%) | catalogued as COSV101356213; called by muse, mutect2, varscan2
- LMNA | c.1416G>A p.Q472= | Silent (SNP) | VAF 24/44 reads (55%) | catalogued as COSV100738566; called by muse, mutect2, varscan2
- LY75 | c.4866C>G p.V1622= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV99716181; called by muse, mutect2, varscan2
- MAGEB6 | c.78G>C p.T26= | Silent (SNP) | VAF 32/49 reads (65%) | catalogued as COSV100983693, COSV66871919; called by muse, mutect2, varscan2
- MYH11 | c.5904C>T p.T1968= | Silent (SNP) | VAF 123/302 reads (41%) | catalogued as COSV100260219, COSV55571045; called by muse, mutect2, varscan2
- OR2T12 | c.183G>A p.L61= | Silent (SNP) | VAF 64/160 reads (40%) | catalogued as COSV100527644; called by muse, mutect2, varscan2
- OR6C75 | c.199C>T p.L67= | Silent (SNP) | VAF 84/213 reads (39%) | catalogued as COSV100595294; called by muse, mutect2, varscan2
- OR7C2 | c.414C>A p.P138= | Silent (SNP) | VAF 68/188 reads (36%) | catalogued as rs985472260, COSV99934457; called by muse, mutect2, varscan2
- PCDHB11 | c.1473C>A p.L491= | Silent (SNP) | VAF 88/217 reads (41%) | catalogued as COSV100696943; called by muse, mutect2, varscan2
- PCLO | c.5409T>C p.S1803= | Silent (SNP) | VAF 60/143 reads (42%) | catalogued as rs1229801126, COSV100429286; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.912T>A p.P304= | Silent (SNP) | VAF 9/102 reads (9%) | catalogued as COSV100544111; called by muse, mutect2
- PRKCG | c.1191G>C p.L397= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV99668701; called by muse, mutect2, varscan2
- PSKH2 | c.255C>A p.T85= | Silent (SNP) | VAF 30/143 reads (21%) | catalogued as COSV99405063; called by muse, mutect2, varscan2
- PTPN14 | c.3171G>A p.K1057= | Silent (SNP) | VAF 96/317 reads (30%) | catalogued as rs1284775561, COSV100872437; called by muse, mutect2, varscan2
- RAB17 | c.612G>A p.A204= | Silent (SNP) | VAF 33/74 reads (45%) | catalogued as rs375159510; called by muse, mutect2, varscan2
- RADIL | c.315G>A p.R105= | Silent (SNP) | VAF 40/117 reads (34%) | catalogued as COSV101271316; called by muse, mutect2, varscan2
- RECQL5 | c.2718C>T p.S906= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as rs772969250, COSV58646495; called by muse, mutect2, varscan2
- SLITRK5 | c.249C>T p.I83= | Silent (SNP) | VAF 89/238 reads (37%) | catalogued as COSV100280524; called by muse, varscan2
- SOS2 | c.2271A>T p.P757= | Silent (SNP) | VAF 50/151 reads (33%) | catalogued as COSV99365643; called by muse, mutect2, varscan2
- ST3GAL3 | c.696T>A p.P232= (on ENST00000361392 / NM_174964.4; = p.P217= on NM_006279.5) | Silent (SNP) | VAF 45/106 reads (42%) | catalogued as COSV99495111; called by muse, mutect2, varscan2
- SYNDIG1L | c.582G>A p.G194= | Silent (SNP) | VAF 37/118 reads (31%) | catalogued as COSV100526428; called by muse, mutect2, varscan2
- TAF6 | c.291C>T p.A97= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100693344; called by muse, mutect2, varscan2
- TCF20 | c.5280C>T p.S1760= | Silent (SNP) | VAF 44/137 reads (32%) | catalogued as rs760202467, COSV100166383; called by muse, mutect2, varscan2
- TCF21 | c.81G>A p.S27= | Silent (SNP) | VAF 44/100 reads (44%) | catalogued as rs967456656, COSV52818823; called by muse, varscan2
- TM7SF2 | c.1188G>A p.Q396= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as rs754635636, COSV99659272; called by muse, mutect2, varscan2
- TRAV8-2 | c.240C>T p.N80= | Silent (SNP) | VAF 85/202 reads (42%) | catalogued as rs1450028297; called by muse, mutect2, varscan2
- USP8 | c.972G>A p.Q324= | Silent (SNP) | VAF 29/46 reads (63%) | catalogued as COSV100208862; called by muse, mutect2, varscan2
- XKR4 | c.915G>T p.L305= | Silent (SNP) | VAF 44/82 reads (54%) | catalogued as COSV100531657; called by muse, mutect2, varscan2
- ZFP69B | c.1467C>G p.S489= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as rs1233735480, COSV100848220; called by muse, mutect2
- ZFYVE16 | c.4317G>A p.Q1439= | Silent (SNP) | VAF 31/51 reads (61%) | catalogued as COSV100566294; called by muse, mutect2, varscan2
- ZNF831 | c.2952G>T p.L984= | Silent (SNP) | VAF 35/51 reads (69%) | catalogued as COSV100925896; called by muse, mutect2, varscan2
- DST | c.4297-2546C>A | Intron (SNP) | VAF 24/81 reads (30%) | catalogued as COSV99753043; called by muse, mutect2, varscan2
- OBSCN | c.11660-1110A>G | Intron (SNP) | VAF 60/152 reads (39%) | catalogued as rs1462255239, COSV99475193; called by muse, mutect2, varscan2
- XPO5 | c.*147A>C | 3'UTR (SNP) | VAF 51/114 reads (45%) | catalogued as COSV99540613; called by muse, mutect2, varscan2
